Somatic mutation profile of tumor specimen ALCH-AC5E-TTP1-A (aliquot ALCH-AC5E-TTP1-A-2-0-D-A49J-36) from ALCHEMIST case ALCH-AC5E, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenosquamous carcinoma; Age at diagnosis: 57.6 years (21,048 days).
Specimen ALCH-AC5E-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7e92f0bb-f731-4aec-bd60-367077caa43e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AC5E-NB1-A (Blood Derived Normal), aliquot ALCH-AC5E-NB1-A-1-0-D-A49J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/52eb8319-0bd7-4a54-84f1-03e6b2ea0001

The open-access MAF lists 73 somatic variants for this specimen: 53 protein-altering or splice-affecting, 17 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 17, 3'UTR 2, Frame Shift Del 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 142/704 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- ADAD2 | c.524C>T p.A175V (on ENST00000315906 / NM_001145400.2; = p.A247V on NM_139174.4) | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as rs1470162944; called by muse, mutect2
- ADAD2 | c.995G>A p.R332H (on ENST00000315906 / NM_001145400.2; = p.R414H on NM_139174.4) | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.125); catalogued as rs371012828; called by muse, mutect2
- AGTR2 | c.1066A>G p.R356G | Missense Mutation (SNP) | VAF 36/554 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as rs1556673869; called by muse, mutect2
- ANAPC15 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 32/286 reads (11%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.04); catalogued as rs982888986, COSV56191427; called by muse, mutect2, varscan2
- ASPM | c.9842G>A p.R3281K | Missense Mutation (SNP) | VAF 24/589 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV54138360; called by muse, mutect2
- CASR | c.1681C>T p.R561C (on ENST00000490131; = p.R638C on NM_000388.4) | Missense Mutation (SNP) | VAF 9/140 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs1185593894, COSV56138364; ClinVar: uncertain significance; called by muse, mutect2
- CIITA | c.3184G>A p.E1062K | Missense Mutation (SNP) | VAF 55/290 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.306); catalogued as rs777187047, COSV60858908; called by muse, mutect2, varscan2
- DCAF8 | c.754A>G p.T252A | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.577); catalogued as rs577012239; called by muse, mutect2, varscan2
- FAM47A | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0.344); catalogued as rs750698635, COSV60496289; called by muse, mutect2, varscan2
- FLII | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs538192881; called by muse, mutect2
- GOLGB1 | c.9395C>T p.P3132L | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs553004218; called by muse, mutect2
- HIF1A | c.1006G>A p.V336I | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); catalogued as COSV60192180; called by muse, mutect2, varscan2
- IGSF10 | c.6259G>A p.D2087N | Missense Mutation (SNP) | VAF 54/586 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201909176, COSV56371983; called by muse, mutect2
- JAM3 | c.730G>A p.G244R | Missense Mutation (SNP) | VAF 46/1040 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs774418995; called by muse, mutect2
- KRTAP10-3 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs782557473, COSV59975304; called by muse, mutect2
- LUZP1 | c.73C>T p.R25C | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs370488038; called by muse, mutect2
- MORC3 | c.1541C>T p.S514L | Missense Mutation (SNP) | VAF 13/273 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.058); catalogued as COSV68203757; called by muse, mutect2
- MYO5A | c.37G>A p.V13I | Missense Mutation (SNP) | VAF 64/540 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as rs1401011577; called by muse, mutect2, varscan2
- NASP | c.1738G>A p.D580N | Missense Mutation (SNP) | VAF 20/252 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.432); catalogued as rs1033232856; called by muse, mutect2
- NLRP1 | c.1124C>T p.S375F | Missense Mutation (SNP) | VAF 33/170 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.424); catalogued as COSV99335763; called by muse, mutect2, varscan2
- PREX1 | c.4346C>T p.S1449F | Missense Mutation (SNP) | VAF 24/239 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV64251430; called by muse, mutect2, varscan2
- PSD | c.1658C>T p.A553V | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.364); catalogued as rs547833956; called by muse, mutect2, varscan2
- PTPRO | c.2933G>A p.R978H (on ENST00000281171 / NM_030667.3; = p.R950H on NM_002848.4) | Missense Mutation (SNP) | VAF 69/701 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868236147; called by muse, mutect2, varscan2
- SHMT1 | c.124A>G p.N42D | Missense Mutation (SNP) | VAF 26/438 reads (6%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs201557147; called by muse, mutect2
- SYNPO | c.379C>A p.P127T | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.118); catalogued as rs1561638214; called by muse, mutect2
- TMPRSS9 | c.559C>T p.R187C (on ENST00000648592; = p.R153C on NM_182973.2) | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.292); catalogued as rs141796619, COSV60232116; called by muse, mutect2
- ZBTB18 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 17/619 reads (3%) | SIFT tolerated (0.32); PolyPhen benign (0.187); catalogued as COSV62397910; called by muse, mutect2
- ALMS1 | c.5960C>A p.S1987Y | Missense Mutation (SNP) | VAF 35/612 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); called by muse, mutect2
- AMBRA1 | c.1094T>A p.L365Q (on ENST00000458649 / NM_001367468.1; = p.L275Q on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- AXIN1 | c.585A>T p.E195D | Missense Mutation (SNP) | VAF 36/586 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2
- BHMG1 | c.644G>A p.G215E | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.13); called by muse, mutect2
- C7orf31 | c.1297A>C p.T433P | Missense Mutation (SNP) | VAF 28/497 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CLSPN | c.2572G>A p.D858N | Missense Mutation (SNP) | VAF 30/398 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.604); called by muse, mutect2
- CPSF4L | c.503T>A p.I168N | Missense Mutation (SNP) | VAF 19/255 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2
- DNAJC19 | c.56-4T>A | Splice Region (SNP) | VAF 59/1626 reads (4%) | called by muse, mutect2
- DOCK10 | c.3290A>G p.D1097G | Missense Mutation (SNP) | VAF 44/315 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- GATA2 | c.673A>C p.S225R | Missense Mutation (SNP) | VAF 11/187 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2
- GLT8D2 | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 19/386 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.027); called by muse, mutect2
- HPN | c.1099C>T p.P367S | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2
- KLK10 | c.749G>T p.C250F | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LPCAT1 | c.646T>C p.C216R | Missense Mutation (SNP) | VAF 29/472 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2
- MGLL | c.328G>A p.D110N (on ENST00000398104 / NM_001003794.2; = p.D120N on NM_007283.6) | Missense Mutation (SNP) | VAF 26/472 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.061); called by muse, mutect2
- NCL | c.416A>G p.N139S | Missense Mutation (SNP) | VAF 25/565 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.091); called by muse, mutect2
- NXPE4 | c.1186C>A p.Q396K (on ENST00000375478 / NM_001077639.2; = p.Q112K on NM_017678.3) | Missense Mutation (SNP) | VAF 14/243 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- PITPNM2 | c.992A>G p.Q331R | Missense Mutation (SNP) | VAF 28/320 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); called by muse, mutect2
- RAD18 | c.1056del p.L353Wfs*20 | Frame Shift Del (DEL) | VAF 22/171 reads (13%) | called by mutect2, varscan2
- RGPD4 | c.2824G>A p.E942K | Missense Mutation (SNP) | VAF 54/1732 reads (3%) | SIFT tolerated (0.28); PolyPhen benign (0.01); called by muse, mutect2
- RPAP1 | c.3971C>T p.S1324L | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- TOM1L2 | c.27C>G p.F9L | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.073); called by muse, mutect2
- TXNIP | c.1061A>T p.D354V | Missense Mutation (SNP) | VAF 30/518 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2
- VWA3A | c.743A>G p.N248S | Missense Mutation (SNP) | VAF 9/151 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.936); called by muse, mutect2
- ZNF525 | c.929A>G p.H310R | Missense Mutation (SNP) | VAF 56/383 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAT2 | c.87G>A p.A29= | Silent (SNP) | VAF 9/142 reads (6%) | called by muse, mutect2
- APOB | c.3249T>A p.S1083= | Silent (SNP) | VAF 41/632 reads (6%) | called by muse, mutect2
- ARHGEF1 | c.873T>C p.V291= | Silent (SNP) | VAF 10/190 reads (5%) | called by muse, mutect2
- CEP170 | c.3702T>A p.P1234= | Silent (SNP) | VAF 52/318 reads (16%) | called by muse, mutect2
- DBN1 | c.339C>T p.D113= | Silent (SNP) | VAF 7/138 reads (5%) | catalogued as rs914125832; called by muse, mutect2
- HTR3A | c.1383G>A p.V461= | Silent (SNP) | VAF 22/474 reads (5%) | catalogued as rs1209482716; called by muse, mutect2
- ISL1 | c.957G>A p.P319= | Silent (SNP) | VAF 33/716 reads (5%) | catalogued as rs772384999; called by muse, mutect2
- KCNQ3 | c.1785C>T p.S595= | Silent (SNP) | VAF 48/549 reads (9%) | called by muse, mutect2
- MRGPRD | c.660C>T p.F220= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as rs1260902926; called by muse, mutect2, varscan2
- MYB | c.1323G>A p.V441= | Silent (SNP) | VAF 51/470 reads (11%) | catalogued as COSV100214982; called by muse, mutect2, varscan2
- NCCRP1 | c.738C>T p.F246= | Silent (SNP) | VAF 7/105 reads (7%) | catalogued as COSV59212447; called by muse, mutect2
- NMT1 | c.54G>A p.Q18= | Silent (SNP) | VAF 21/195 reads (11%) | catalogued as rs1229832497; called by muse, mutect2, varscan2
- PCDHGA10 | c.1494C>T p.D498= | Silent (SNP) | VAF 29/257 reads (11%) | catalogued as COSV53928905; called by muse, mutect2, varscan2
- PSME4 | c.2958T>C p.A986= | Silent (SNP) | VAF 12/304 reads (4%) | called by muse, mutect2
- RMDN2 | c.516A>G p.T172= (on ENST00000354545 / NM_001322212.2; = p.T350= on NM_144713.5) | Silent (SNP) | VAF 10/268 reads (4%) | called by muse, mutect2
- SPATA31D1 | c.2496A>G p.V832= | Silent (SNP) | VAF 227/1078 reads (21%) | called by muse, mutect2, varscan2
- VPS8 | c.1548G>T p.A516= (on ENST00000625842 / NM_001349294.1; = p.A514= on NM_015303.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 38/279 reads (14%) | catalogued as COSV54993315; called by muse, mutect2, varscan2
- PEX19 | c.*1828C>G | 3'UTR (SNP) | VAF 44/940 reads (5%) | catalogued as rs1005544423; called by muse, mutect2
- TRAPPC9 | c.1008+34G>A | Intron (SNP) | VAF 22/422 reads (5%) | catalogued as rs376659925; called by muse, mutect2
- UQCRB | c.*532A>G | 3'UTR (SNP) | VAF 54/333 reads (16%) | called by muse, mutect2, varscan2
